Somatic mutation profile of tumor specimen BA2046D (aliquot aq-BA2046D) from BEATAML1.0 case 2265, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.7 years (22,553 days).
Specimen BA2046D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c84982e5-b66b-4d37-9a8a-cb1f388bc9ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2946D (Solid Tissue Normal), aliquot aq-BA2946D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0a5e391-2b14-4497-8fef-f31a3d8d3227

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 2, Frame Shift Del 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SRSF2 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.57); PolyPhen benign (0.398); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by muse, mutect2, varscan2
- FLG | c.3157C>A p.Q1053K | Missense Mutation (SNP) | VAF 142/486 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.826); catalogued as rs766514474; called by muse, mutect2, varscan2
- KLK6 | c.19G>T p.V7L | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV59565414; called by muse, mutect2, varscan2
- MYB | c.1280A>G p.H427R | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.193); catalogued as rs1346027915; called by muse, varscan2
- SKOR1 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100408210; called by mutect2, varscan2
- TCP10L2 | c.749C>T p.T250M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs761436101, COSV52083706; called by muse, mutect2, varscan2
- ARHGAP10 | c.27C>A p.S9R | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BRCC3 | c.890dup p.H297Qfs*55 | Frame Shift Ins (INS) | VAF 3/23 reads (13%) | called by mutect2, pindel
- CRHR2 | c.1094A>G p.E365G | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MBTD1 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.011); called by muse, mutect2
- MYB | c.1275del p.I425Mfs*5 | Frame Shift Del (DEL) | VAF 15/106 reads (14%) | called by pindel, varscan2
- MYO6 | c.72T>G p.I24M | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- SI | c.4334G>A p.S1445N | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- SLITRK2 | c.314C>A p.A105E | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- STARD13 | c.793A>T p.T265S (on ENST00000336934 / NM_001243476.3; = p.T147S on NM_052851.3) | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAH9 | c.3984C>T p.N1328= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs193103626, COSV99304522; called by muse, mutect2, varscan2
- NCOA7 | c.2157C>T p.A719= | Silent (SNP) | VAF 42/123 reads (34%) | called by muse, mutect2, varscan2
- TUBB8P7 | n.1497G>A | RNA (SNP) | VAF 26/99 reads (26%) | called by muse, mutect2, varscan2
